FM case AD5737 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon.
https://portal.gdc.cancer.gov/cases/9a07f78f-3301-4e54-b835-df3adb2f6054

Female, 42.3 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the appendix; primary biopsied or resected from the appendix. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
